Surgical pathology report (de-identified scan), TCGA case TCGA-62-A46O, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-A46O-01A (Primary Tumor).

Pathology Report-Summary:

Material:

lung, right, lower lobe: 14.0 x 11.0 x 10.0 cm

tumor: 6.0 x 5.5 x 4.5 cm

Diagnosis:

Adenocarcinoma (NOS)

Infiltration of pleura visceralis

pT2, pN0 (0/22), pMx, G3

ICD-O-3

adenocarcinoma, NOS 8140/3

Site: lung, lower lobe C34.3

hw
9/24/12

Supplementary examinations:

IHC:

tumor cells positive for: CK7, CEA

some tumor cells positive for TTF1, Vimentin

tumor cells negative for: Chromogranin A, Synaptophysin, NSE, CK13, CK14, CD56

Ki-67: 40-50%

Pathologist:

IHPAA Discrepancy		
Case Circled:		
Case Verified:		
Case Reviewed:		

hw
9/24/12

Source: NCI Genomic Data Commons file 5f566c68-765f-42cf-8167-2d7b1d26cb73 (TCGA-62-A46O.C1EAC8C9-2538-4FEB-9DFF-FF9AE7A20F42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).